Somatic mutation profile of tumor specimen TCGA-IG-A50L-01A (aliquot TCGA-IG-A50L-01A-11D-A27G-09) from TCGA case TCGA-IG-A50L, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 58.1 years (21,214 days).
Specimen TCGA-IG-A50L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dd4d4a6-e5b2-41f2-8f28-1db3644e104f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A50L-10A (Blood Derived Normal), aliquot TCGA-IG-A50L-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d029ca1b-6d39-45d0-95f2-27ac7540a643

The open-access MAF lists 114 somatic variants for this specimen: 86 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 24, Nonsense Mutation 6, Frame Shift Ins 4, Intron 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 38/95 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960135, COSV67960407, COSV67962953; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 137/270 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALS2CL | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.355); catalogued as rs1203620915; called by muse, mutect2, varscan2
- ANKFY1 | c.2696C>A p.S899* (on ENST00000341657 / NM_001330063.2; = p.S900* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV58919774; called by muse, mutect2, varscan2
- ANKS1A | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs779266197; called by muse, mutect2, varscan2
- ARHGAP5 | c.4201A>G p.I1401V (on ENST00000345122 / NM_001030055.2; = p.I1400V on NM_001173.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs779238726; called by muse, mutect2, varscan2
- BRSK1 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs769516314, COSV58665178; called by muse, mutect2, varscan2
- CASP1 | c.502A>G p.I168V (on ENST00000436863 / NM_033292.4; = p.I147V on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376117763; called by muse, mutect2, varscan2
- DGKB | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99034042; called by muse, mutect2, varscan2
- DUS4L | c.783C>G p.I261M | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV50052024; called by muse, mutect2
- EFCAB1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100030601; called by muse, mutect2, varscan2
- FLRT1 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1475875325; called by muse, mutect2
- H1-2 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.902); catalogued as COSV59189752; called by muse, mutect2
- ILDR1 | c.1487G>A p.R496H (on ENST00000344209 / NM_001199799.2; = p.R452H on NM_175924.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs757986659, COSV56550175; called by muse, mutect2, varscan2
- LGSN | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs780163823; called by muse, mutect2, varscan2
- MOXD1 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1320822814; called by muse, mutect2, varscan2
- MVB12A | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.751); catalogued as rs773765047, COSV57678814; called by muse, mutect2, varscan2
- NEXMIF | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50025876; called by muse, mutect2, varscan2
- NOTCH1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs753661188, COSV53075917; called by muse, mutect2, varscan2
- OLFM3 | c.1265C>A p.T422N (on ENST00000338858 / NM_001288821.1; = p.T402N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58798137; called by muse, mutect2, varscan2
- OR4K1 | c.92T>C p.F31S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53461324; called by muse, mutect2, varscan2
- OR5T1 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV57304103; called by muse, mutect2, varscan2
- PCSK2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.297); catalogued as rs1443393363; called by muse, mutect2
- PGAP4 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs928790005; called by muse, mutect2, varscan2
- STYXL2 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99609850; called by muse, mutect2, varscan2
- TTN | c.72424C>T p.R24142W (on ENST00000591111; = p.R16718W on NM_003319.4) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | PolyPhen probably damaging (0.961); catalogued as rs758010128; called by muse, mutect2, varscan2
- TYK2 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs143538128; called by muse, mutect2, varscan2
- ZXDB | c.1480T>C p.S494P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100885773; called by muse, mutect2, varscan2
- AOPEP | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- ASB12 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BOD1L1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CARMIL2 | c.3323G>A p.R1108H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CCDC82 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- CCNL2 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP4 | c.1930G>T p.V644F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- COL21A1 | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); called by mutect2, varscan2
- COL25A1 | c.1301A>C p.N434T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CRB1 | c.79T>C p.C27R | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAAF5 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DPPA4 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPRX | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- EMC3 | c.389dup p.M130Ifs*20 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- EPOR | c.482A>T p.H161L | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ESRRA | c.446_449dup p.L151Afs*56 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- F8 | c.3948A>G p.I1316M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FARSA | c.284dup p.M95Ifs*27 | Frame Shift Ins (INS) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- FAT3 | c.11447G>A p.S3816N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRMD8 | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GK2 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- IBTK | c.2369G>A p.R790K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFT88 | c.1175C>A p.A392E (on ENST00000319980 / NM_001318493.2; = p.A383E on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGF2R | c.3193C>T p.R1065* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- KIAA0408 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- KIF16B | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIF1A | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNOP1 | c.1279A>T p.K427* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- KRT15 | c.1358A>G p.K453R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KRTDAP | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LCE2A | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAP4K5 | c.2182del p.S728Pfs*4 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- MIA3 | c.4274A>G p.N1425S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by muse, mutect2
- MS4A10 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC16 | c.6965C>T p.A2322V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MYH2 | c.3785T>C p.L1262P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- NOS3 | c.2824G>T p.V942F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- NOX4 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR1H4 | c.77dup p.M27Hfs*62 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- OR4Q3 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- OR5M8 | c.69A>T p.Q23H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- OTP | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCDHA7 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- RAVER2 | c.129C>G p.D43E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- ROS1 | c.1774A>G p.S592G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by mutect2, varscan2
- SCN2A | c.4867A>T p.T1623S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SON | c.3194C>A p.S1065Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPAG9 | c.2033T>A p.L678Q (on ENST00000262013 / NM_001130528.3; = p.L664Q on NM_003971.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNIP1 | c.1901G>C p.G634A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- VCPIP1 | c.3341C>T p.S1114F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- WDR17 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR46 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WFDC8 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZMYM4 | c.2656A>G p.I886V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ZNF335 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF676 | c.1563C>A p.F521L (on ENST00000650058; = p.F489L on NM_001001411.3) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ZNF676 | c.855C>A p.Y285* (on ENST00000650058; = p.Y253* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- ZNF721 | c.1604A>C p.H535P (on ENST00000338977; = p.H547P on NM_133474.4) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BSDC1 | c.387A>G p.P129= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- CAND1 | c.3369A>G p.T1123= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV73389528; called by muse, mutect2, varscan2
- CDH10 | c.2145T>C p.N715= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1476582251; called by muse, mutect2, varscan2
- GALC | c.1029A>G p.V343= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1389188299; called by muse, mutect2
- KIAA1549L | c.3933C>G p.P1311= (on ENST00000321505; = p.P1608= on NM_012194.3) | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- L3MBTL1 | c.921C>A p.A307= (on ENST00000418998 / NM_001377303.1; = p.A217= on NM_015478.7) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- LPO | c.936C>T p.S312= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs369628308; called by muse, mutect2, varscan2
- MAP7D3 | c.1152A>G p.A384= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- MUC16 | c.1329T>A p.S443= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- NPRL3 | c.1329C>T p.N443= (on ENST00000611875 / NM_001077350.3; = p.N418= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs559760517; called by muse, mutect2, varscan2
- NUP160 | c.1675C>T p.L559= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- NYAP2 | c.1881T>A p.P627= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- PCSK7 | c.1611A>T p.P537= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- PTH2R | c.1041C>T p.T347= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- PTPN2 | c.76C>A p.R26= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV58996612; called by muse, mutect2, varscan2
- PTPRS | c.4476G>A p.R1492= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- SERPINB9 | c.639C>G p.R213= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- SMC5 | c.1434A>G p.K478= | Silent (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- THUMPD3 | c.1383A>T p.V461= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100560518; called by muse, mutect2
- TRPV5 | c.1044C>T p.V348= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- TSPAN9 | c.549G>A p.T183= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1330798079; called by muse, mutect2, varscan2
- ZNF609 | c.2496A>T p.G832= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ZNF616 | c.1308T>C p.T436= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- ZNF804B | c.3534T>C p.L1178= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- AC016747.4 | n.500C>A | RNA (SNP) | VAF 15/69 reads (22%) | catalogued as COSV54378326; called by muse, mutect2, varscan2
- CTSL3P | n.297G>A | RNA (SNP) | VAF 14/126 reads (11%) | catalogued as rs1312828142; called by muse, mutect2, varscan2
- OBSCN | c.11659+4429A>G | Intron (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- PRKACB | c.47-5845G>A | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as rs756910770, COSV100854013; called by muse, varscan2
